Somatic mutation profile of tumor specimen TARGET-10-PANVFF-09A (aliquot TARGET-10-PANVFF-09A-01D) from TARGET case TARGET-10-PANVFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,811 days).
Specimen TARGET-10-PANVFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7bd1e82-332e-4eae-8e2c-09f1838019c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVFF-14A (Bone Marrow Normal), aliquot TARGET-10-PANVFF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d167d0-8429-48b7-a626-a6e9fa2b3e82

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHRS9 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771507025; called by muse, mutect2, varscan2
- SPATA2L | c.717C>T p.D239= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs752764428, COSV57046322; called by muse, mutect2, varscan2
- EIF3I | c.-23G>A | 5'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1192+53G>A | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs187185494; called by muse, mutect2, varscan2
